Somatic mutation profile of tumor specimen 0DP4Q2 from CCDI case PBCCXK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.3 years (3,039 days).
Specimen 0DP4Q2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e995daed-748a-4d2c-a1cf-de5634efc067.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP4OZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/881c3785-5a30-45ef-9dd3-86684b450b47

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs150890005; ClinVar: uncertain significance; called by muse, varscan2
- EPX | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs755977833; called by muse, mutect2
- GNE | c.1997A>G p.N666S (on ENST00000396594 / NM_001128227.3; = p.N635S on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/422 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- UGT2B28 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.227); called by muse, mutect2, varscan2
